Somatic mutation profile of tumor specimen TCGA-ZF-A9R0-01A (aliquot TCGA-ZF-A9R0-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9R0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.7 years (30,222 days).
Specimen TCGA-ZF-A9R0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46b64c83-a1b4-4d0f-be70-d09280f2e9c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R0-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R0-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5977e21a-04a7-4b5f-b5aa-c924abca6043

The open-access MAF lists 223 somatic variants for this specimen: 159 protein-altering or splice-affecting, 55 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 55, Nonsense Mutation 16, Intron 3, 5'UTR 3, RNA 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV57923712; called by muse, mutect2, varscan2
- ABCA4 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64671448, COSV64678007; called by muse, mutect2, varscan2
- ACO2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1353194449, COSV53442981; called by muse, mutect2, varscan2
- ACVR1B | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV57777462; called by muse, mutect2, varscan2
- ADGRA3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51563524; called by muse, mutect2, varscan2
- ADGRV1 | c.18310G>T p.E6104* | Nonsense Mutation (SNP) | VAF 50/83 reads (60%) | catalogued as CM149650, COSV101316259; called by muse, mutect2, varscan2
- AGO2 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55047935; called by muse, mutect2
- AK2 | c.469G>C p.E157Q (on ENST00000354858; = p.E199Q on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61467802; called by muse, varscan2
- AKR1E2 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1363764927, COSV53630604; called by muse, mutect2
- ALYREF | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV58668540; called by muse, mutect2, varscan2
- ANK2 | c.10795C>G p.H3599D | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52163271; called by muse, mutect2, varscan2
- APOL6 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101291006; called by muse, mutect2, varscan2
- APOL6 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV68749386; called by muse, mutect2, varscan2
- ATP1B3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs1354628611, COSV53949959; called by muse, mutect2, varscan2
- BLZF1 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV61393424, COSV61395133; called by muse, mutect2, varscan2
- BNC2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.253); catalogued as COSV66148244; called by muse, mutect2, varscan2
- BRAP | c.1067A>G p.Y356C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59536844; called by muse, mutect2, varscan2
- BRCA2 | c.9041C>T p.S3014L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66454517; called by muse, mutect2, varscan2
- C20orf194 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52696419; called by muse, mutect2, varscan2
- C2CD2L | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1460485842, COSV60884107; called by muse, mutect2, varscan2
- CCNB1 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV56510195; called by muse, mutect2, varscan2
- CCNB1 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56510207; called by muse, mutect2, varscan2
- CCNE2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.108); catalogued as COSV57376202; called by muse, mutect2, varscan2
- CD46 | c.476-1G>C p.X159_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as rs1441390681, COSV59733504; called by muse, mutect2, varscan2
- CDC42BPB | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1196626669, COSV63475154; called by muse, mutect2, varscan2
- CDK8 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1424308901, COSV67420930, COSV67421506; called by muse, mutect2, varscan2
- CELSR2 | c.7723A>G p.T2575A | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.957); catalogued as COSV54772625; called by muse, mutect2, varscan2
- CEMIP | c.3019C>G p.Q1007E | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54993371; called by muse, mutect2, varscan2
- CENPP | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV65038953; called by muse, mutect2, varscan2
- CLCA1 | c.2060G>C p.R687T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV52328193; called by muse, mutect2, varscan2
- CLIC6 | c.1466T>A p.F489Y (on ENST00000360731 / NM_001317009.2; = p.F471Y on NM_053277.3) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62447871; called by muse, mutect2, varscan2
- CNST | c.621G>C p.E207D | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63620458; called by muse, mutect2, varscan2
- CNST | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.799); catalogued as rs1171098284, COSV63620460; called by muse, mutect2, varscan2
- COL5A2 | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV66409999, COSV66410164; called by muse, mutect2, varscan2
- CSMD3 | c.10288C>G p.H3430D (on ENST00000297405 / NM_001363185.1; = p.H3261D on NM_052900.3) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV52106150; called by muse, mutect2, varscan2
- CXorf58 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV64858256; called by muse, varscan2
- DAB2 | c.1841C>G p.S614C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV57914666; called by muse, mutect2, varscan2
- DNAL1 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs1235974438, COSV60727399, COSV60727414; called by mutect2, varscan2
- DSG4 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57392279; called by muse, mutect2, varscan2
- ELF3 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403955742, COSV62837492; called by muse, varscan2
- ERO1A | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.255); catalogued as COSV67470716; called by muse, mutect2, varscan2
- ESYT2 | c.2725G>C p.D909H (on ENST00000613624; = p.D833H on NM_020728.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV51751463; called by muse, mutect2
- FBF1 | c.835G>T p.D279Y (on ENST00000586717; = p.D293Y on NM_001319193.1) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59865275; called by muse, mutect2, varscan2
- FREM2 | c.8799G>A p.M2933I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54839252, COSV99746811; called by muse, mutect2, varscan2
- FREM2 | c.8975G>C p.G2992A | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54839262; called by muse, mutect2, varscan2
- GCM2 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 56/92 reads (61%) | catalogued as COSV101069579; called by muse, mutect2, varscan2
- GCOM1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99985162; called by muse, mutect2, varscan2
- GMEB2 | c.1406T>C p.F469S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56607299; called by muse, mutect2
- GPR179 | c.5387G>A p.G1796D (on ENST00000621958; = p.G1795D on NM_001004334.4) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as rs1258692236; called by muse, mutect2, varscan2
- GPRIN2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV65401121; called by muse, mutect2, varscan2
- H3C11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV58899154; called by muse, mutect2, varscan2
- HLCS | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV60794013; called by muse, mutect2, varscan2
- ITPR3 | c.7310C>T p.S2437L | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs139781035; called by muse, mutect2, varscan2
- KCNJ2 | c.1005C>A p.H335Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54661871; called by muse, mutect2, varscan2
- KDM6A | c.2117C>G p.S706* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100938453; called by muse, mutect2, varscan2
- KIDINS220 | c.3637G>T p.D1213Y | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56753985; called by muse, mutect2, varscan2
- KIF14 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66261903; called by muse, mutect2, varscan2
- KNOP1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV54928361; called by muse, mutect2, varscan2
- KTN1 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.296); catalogued as COSV68023459; called by muse, mutect2, varscan2
- LHX2 | c.1040C>G p.S347W | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65318414, COSV65318445; called by muse, mutect2, varscan2
- LIPE | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as rs1457890696, COSV54922229, COSV54923092; called by muse, mutect2, varscan2
- LNPEP | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV51478273; called by muse, mutect2, varscan2
- LNX1 | c.473C>T p.T158M (on ENST00000263925 / NM_001126328.3; = p.T62M on NM_032622.2) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1337782350, COSV55786065; called by muse, mutect2, varscan2
- LPCAT3 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV54645926; called by muse, mutect2, varscan2
- MADD | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60624665; called by muse, mutect2, varscan2
- MAPK15 | c.1592C>A p.S531* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100568029, COSV62027230; called by muse, mutect2, varscan2
- MEGF6 | c.1713G>C p.Q571H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV53890410; called by muse, mutect2, varscan2
- MTOR | c.6145G>A p.E2049K | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV63872065, COSV63872289; called by muse, varscan2
- MTOR | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63872070; called by muse, varscan2
- MYH2 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV55439267; called by muse, mutect2, varscan2
- NBEAL1 | c.4647G>C p.M1549I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV71374445; called by muse, mutect2, varscan2
- NFKBIL1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187793022, COSV58214637; called by muse, mutect2, varscan2
- NIN | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs773917916, COSV55383009; called by muse, mutect2, varscan2
- NUB1 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV63426719; called by muse, mutect2, varscan2
- NUFIP1 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV64790548, COSV64791251; called by muse, mutect2, varscan2
- NUFIP1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV64791253; called by muse, mutect2, varscan2
- NVL | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55871448, COSV55872854; called by muse, mutect2, varscan2
- OR13J1 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65069801, COSV65069904; called by mutect2, varscan2
- OR2M3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs145845024, COSV101513388; called by muse, mutect2, varscan2
- OR5T2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57589418; called by muse, mutect2, varscan2
- PADI2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs187842443; called by muse, mutect2, varscan2
- PARD3 | c.2800G>A p.D934N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60750860; called by muse, mutect2, varscan2
- PARN | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 65/139 reads (47%) | catalogued as rs1476873980, COSV100421218; called by muse, mutect2, varscan2
- PCDHA8 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.321); catalogued as rs782725221, COSV100970716, COSV65336294; called by muse, mutect2, varscan2
- PEAK1 | c.3160G>C p.E1054Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs762652758, COSV56936526; called by muse, mutect2, varscan2
- PKN2 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV65143072; called by muse, varscan2
- PLCH1 | c.777G>C p.K259N (on ENST00000340059 / NM_001130960.2; = p.K271N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV58198627; called by muse, mutect2, varscan2
- PLEKHG5 | c.1015G>C p.E339Q (on ENST00000400915 / NM_001042663.3; = p.E302Q on NM_020631.6) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100556170, COSV61702357; called by muse, mutect2, varscan2
- PLXND1 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV60714214; called by muse, mutect2, varscan2
- PLXND1 | c.5145G>T p.Q1715H | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1205245553, COSV60714220; called by muse, mutect2, varscan2
- POGK | c.1109T>C p.L370S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63311650; called by muse, mutect2, varscan2
- POLE | c.724C>G p.H242D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.326); catalogued as COSV57681059; called by muse, mutect2, varscan2
- PON1 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV55931681; called by muse, mutect2, varscan2
- PUS3 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57103243; called by muse, mutect2, varscan2
- PYGM | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV51217856; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 120/189 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774641180, COSV54760407; called by muse, mutect2, varscan2
- RAD23A | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV57126139; called by muse, mutect2, varscan2
- RALGAPA2 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52488981; called by muse, mutect2
- RGP1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV65239597; called by muse, mutect2
- RGS7 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100469571; called by muse, mutect2, varscan2
- RICTOR | c.3586G>C p.E1196Q | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.384); catalogued as COSV57122606; called by muse, mutect2, varscan2
- RIPK4 | c.1792G>C p.E598Q (on ENST00000352483; = p.E550Q on NM_020639.3) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV60187592; called by muse, mutect2, varscan2
- RNF40 | c.1696C>G p.P566A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1368638431, COSV61214950; called by muse, mutect2, varscan2
- RPH3A | c.134G>T p.R45M (on ENST00000389385 / NM_001143854.2; = p.R41M on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV66991248; called by muse, mutect2, varscan2
- RPL15 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1331849221, COSV100323270; called by muse, mutect2, varscan2
- RPL19 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56635637; called by muse, mutect2, varscan2
- RRBP1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55700936; called by muse, mutect2, varscan2
- SARAF | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99822812; called by muse, mutect2, varscan2
- SELENOP | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV72484714; called by muse, mutect2, varscan2
- SERINC3 | c.171G>C p.Q57H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV54856852; called by muse, mutect2, varscan2
- SFMBT2 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1308614100, COSV62810238; called by muse, mutect2, varscan2
- SFXN3 | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56520064; called by muse, mutect2, varscan2
- SH3BP2 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100697001; called by muse, mutect2, varscan2
- SHC1 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540270618, COSV58316261; called by muse, mutect2, varscan2
- SLC25A13 | c.140T>A p.I47N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV55707810; called by muse, mutect2, varscan2
- SLC25A17 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV54351355; called by muse, mutect2, varscan2
- SLC41A3 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.054); catalogued as COSV59988404; called by muse, mutect2, varscan2
- SLC44A2 | c.1494C>T p.L498= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as COSV59837019; called by muse, mutect2, varscan2
- SLC5A11 | c.1683C>A p.D561E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV61741813; called by muse, mutect2, varscan2
- SLIT3 | c.4525G>C p.E1509Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV60610346; called by muse, mutect2, varscan2
- SPARC | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50558630; called by muse, mutect2, varscan2
- ST14 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99598984; called by muse, mutect2
- STAB2 | c.5594G>A p.R1865Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs544606835, COSV66339623; called by muse, mutect2, varscan2
- SYCP1 | c.2613G>C p.L871F | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1448576471, COSV65697830; called by muse, mutect2, varscan2
- SYNE3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1322613166, COSV62079777; called by muse, mutect2, varscan2
- TIGD7 | c.1413G>C p.Q471H | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51916114; called by muse, mutect2, varscan2
- TLN1 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100148035; called by muse, mutect2
- TLN2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV60890205; called by muse, mutect2, varscan2
- TM9SF4 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.31); catalogued as COSV54107436; called by muse, mutect2, varscan2
- TMEM52 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57069510; called by muse, mutect2, varscan2
- TMEM98 | c.357G>C p.M119I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55582870, COSV55583617; called by muse, mutect2, varscan2
- TMX4 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55680815; called by muse, mutect2, varscan2
- TNIK | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV52673956; called by muse, mutect2, varscan2
- TOP1 | c.221C>G p.S74* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV63692716; called by muse, mutect2, varscan2
- TRIM28 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99449305; called by muse, mutect2, varscan2
- TRIM37 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as rs929301857, COSV51884163; called by muse, mutect2, varscan2
- TRIM37 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV51881874; called by muse, mutect2, varscan2
- TRNT1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52408357; called by muse, mutect2, varscan2
- TSN | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV101067449, COSV67605412; called by muse, mutect2, varscan2
- TTC16 | c.1967C>A p.S656* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100263140, COSV60161917; called by muse, mutect2, varscan2
- UNC45A | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1445026721, COSV67816425; called by muse, mutect2, varscan2
- UNC45A | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 36/101 reads (36%) | catalogued as COSV101266003; called by muse, mutect2, varscan2
- USH2A | c.4702G>C p.E1568Q | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56375734; called by muse, mutect2, varscan2
- VCPIP1 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs1190772424, COSV60047523; called by muse, mutect2, varscan2
- VSIG2 | c.297dup p.T100Hfs*11 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs766405238; called by mutect2, varscan2
- WASHC2C | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV100314146; called by muse, mutect2, varscan2
- XPR1 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100851511, COSV62556970; called by muse, mutect2, varscan2
- ZC3H12A | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as COSV66104141; called by muse, mutect2, varscan2
- ZCCHC7 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59719527; called by muse, mutect2, varscan2
- ZMYND8 | c.2045C>G p.S682* (on ENST00000311275 / NM_001363741.2; = p.S702* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 97/209 reads (46%) | catalogued as COSV99521031; called by muse, mutect2, varscan2
- ZNF225 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53471811; called by muse, mutect2, varscan2
- ZNF528 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs759402338, COSV64619510; called by muse, mutect2, varscan2
- ZNF592 | c.2336C>G p.S779C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55437093; called by muse, mutect2
- ZNF782 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV56652801; called by muse, mutect2, varscan2
- ZSWIM4 | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as COSV54322218; called by muse, mutect2, varscan2
- ADH1C | c.185_187del p.L62del | In Frame Del (DEL) | VAF 49/91 reads (54%) | called by mutect2, pindel, varscan2
- MED13 | c.5538_5540dup p.W1846dup | In Frame Ins (INS) | VAF 14/130 reads (11%) | called by mutect2, pindel
- TPR | c.5941del p.M1981Wfs*105 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel
- ABCA4 | c.1908G>A p.Q636= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as CM983372, COSV64673912; called by muse, mutect2, varscan2
- APAF1 | c.2106C>T p.V702= (on ENST00000551964 / NM_181861.2; = p.V691= on NM_001160.3) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV59664387; called by muse, mutect2, varscan2
- ARHGAP32 | c.1371G>A p.L457= (on ENST00000310343 / NM_001378025.1; = p.L108= on NM_014715.4) | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV59848615; called by muse, mutect2, varscan2
- ATP2B1 | c.1650G>A p.L550= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV53808031; called by muse, mutect2, varscan2
- C1GALT1 | c.498G>A p.L166= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV56178651; called by muse, mutect2, varscan2
- C4BPA | c.543C>T p.I181= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV65536493; called by muse, mutect2, varscan2
- CADPS | c.87C>T p.S29= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1356170443, COSV99339895; called by muse, mutect2, varscan2
- CDH17 | c.1680G>A p.V560= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV50329213; called by muse, mutect2
- CENPI | c.1890C>T p.F630= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV54501111, COSV54503042; called by muse, mutect2, varscan2
- COL4A2 | c.4950C>T p.F1650= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs776842061, COSV64628730; called by muse, mutect2, varscan2
- CRYBA4 | c.327C>A p.I109= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV61322026; called by muse, mutect2, varscan2
- CXorf58 | c.850C>T p.L284= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV64858251, COSV64858484; called by muse, varscan2
- DLG2 | c.399A>T p.I133= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV54648101; called by muse, mutect2, varscan2
- DOCK2 | c.5229C>G p.L1743= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV56960795; called by muse, mutect2, varscan2
- FBN3 | c.7671C>T p.F2557= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1342789515, COSV54455441; called by muse, mutect2, varscan2
- FCRL5 | c.363G>C p.L121= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV62515005; called by muse, mutect2, varscan2
- GNE | c.2233C>T p.L745= (on ENST00000396594 / NM_001128227.3; = p.L714= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV64952018; called by muse, mutect2
- GRK6 | c.711C>T p.I237= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV62682696; called by muse, mutect2, varscan2
- GSC2 | c.603G>A p.P201= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs782299479, COSV50082938; called by muse, mutect2, varscan2
- IER2 | c.165C>G p.L55= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99460303; called by muse, mutect2, varscan2
- KCNH3 | c.2766G>A p.S922= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs140591831; called by muse, mutect2, varscan2
- KCNJ15 | c.748C>T p.L250= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV60811001; called by muse, mutect2, varscan2
- KIAA1958 | c.1818G>C p.R606= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV61724024; called by muse, mutect2, varscan2
- KIAA2013 | c.1878C>T p.F626= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100927140; called by muse, mutect2, varscan2
- LGR4 | c.2691C>T p.S897= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs201557941, COSV58726039; called by muse, mutect2, varscan2
- MAP4K5 | c.2037G>A p.V679= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50155179; called by muse, mutect2, varscan2
- MIEF1 | c.315C>T p.F105= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs924224201, COSV57479057; called by muse, mutect2, varscan2
- MYH6 | c.1398C>T p.F466= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs745448722, COSV62448949; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFATC2IP | c.648C>A p.L216= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV57910330; called by muse, mutect2, varscan2
- NUP98 | c.153C>G p.L51= | Silent (SNP) | VAF 96/185 reads (52%) | catalogued as COSV61432543; called by muse, mutect2, varscan2
- OR5I1 | c.600C>G p.L200= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV56888793; called by muse, mutect2, varscan2
- OR8B2 | c.498C>G p.L166= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100899456; called by muse, mutect2
- PHLDA3 | c.309C>A p.V103= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV66210736, COSV66210818; called by muse, mutect2, varscan2
- PKD2 | c.2349G>A p.E783= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV52938501; called by muse, mutect2, varscan2
- PRDM13 | c.1830C>T p.F610= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs1305593098, COSV65029845, COSV65030252; called by muse, mutect2, varscan2
- RIDA | c.276C>T p.V92= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV54704815; called by muse, mutect2, varscan2
- RIPK4 | c.1368G>A p.K456= (on ENST00000352483; = p.K408= on NM_020639.3) | Silent (SNP) | VAF 70/183 reads (38%) | catalogued as rs191281724, COSV60187598; called by muse, mutect2, varscan2
- RRM2B | c.267C>T p.I89= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1214441777, COSV52567009; called by muse, mutect2, varscan2
- SERPINA12 | c.375G>A p.Q125= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as COSV57943677, COSV57943932; called by muse, varscan2
- SETD6 | c.1335G>A p.A445= (on ENST00000219315 / NM_001160305.4; = p.A421= on NM_024860.3) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs368881599; called by muse, mutect2, varscan2
- SLC9A9 | c.1497G>A p.L499= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV57228835; called by muse, mutect2, varscan2
- SMG7 | c.3413G>A p.*1138= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100750471; called by muse, mutect2, varscan2
- STAB2 | c.7404C>T p.I2468= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1261572648, COSV66339629; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1803G>A p.L601= | Silent (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- SYT17 | c.1248G>A p.K416= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs760150714, COSV62546419; called by muse, mutect2, varscan2
- TBC1D20 | c.597G>A p.V199= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV62612842; called by muse, mutect2, varscan2
- TMC4 | c.1503C>T p.L501= (on ENST00000617472 / NM_001145303.3; = p.L495= on NM_144686.4) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55827337; called by muse, mutect2, varscan2
- TMEM184B | c.1203C>T p.L401= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs190768273, COSV58299121; called by muse, mutect2, varscan2
- TRANK1 | c.6988A>C p.R2330= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV57151930; called by muse, mutect2, varscan2
- U2AF2 | c.786C>T p.F262= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1474538101, COSV58274070; called by muse, mutect2, varscan2
- UBE2M | c.405C>G p.L135= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV53396965; called by muse, mutect2, varscan2
- UBE2M | c.330C>G p.V110= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs200322455, COSV53396988; called by muse, mutect2, varscan2
- VAT1 | c.828G>A p.L276= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs766799454, COSV55896355; called by muse, mutect2, varscan2
- WFDC10A | c.145C>T p.L49= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs767438113, COSV58096814; called by muse, mutect2, varscan2
- ZNF318 | c.1650C>T p.S550= | Silent (SNP) | VAF 56/321 reads (17%) | catalogued as rs368138450; called by muse, mutect2, varscan2
- CALCR | c.52-3291G>A | Intron (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100810721; called by muse, mutect2, varscan2
- CES2 | c.-23G>A | 5'UTR (SNP) | VAF 40/133 reads (30%) | catalogued as rs768553750, COSV57696939; called by muse, mutect2, varscan2
- KLRA1P | n.247C>T | RNA (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86028C>G | Intron (SNP) | VAF 62/101 reads (61%) | catalogued as COSV72278045; called by muse, mutect2, varscan2
- MFRP | chr11:119344874 C>T | 5'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as rs778144527, COSV64128419; ClinVar: uncertain significance; called by muse, varscan2
- NCL | c.1832+95C>T | Intron (SNP) | VAF 33/64 reads (52%) | catalogued as COSV100502422; called by muse, mutect2, varscan2
- PTN | c.-222C>T | 5'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as COSV61968251; called by muse, mutect2, varscan2
- RPL26P30 | n.728C>T | RNA (SNP) | VAF 73/133 reads (55%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 12/19 reads (63%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
